Surgical pathology report (de-identified scan), TCGA case TCGA-G7-6797, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-6797-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. BX LEFT KIDNEY #1
- B. BX LEFT KIDNEY #2
- C. LEFT KIDNEY

SPECIMEN(S):

- A. BX LEFT KIDNEY #1
- B. BX LEFT KIDNEY #2
- C. LEFT KIDNEY

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA/FSB-biopsy of left kidney #1, #2: No definite evidence of malignancy; Dr. has reviewed this case and concurs.

Diagnosis called by Dr. to Dr. at [REDACTED]

GROSS DESCRIPTION:

A. BX LEFT KIDNEY #1

Received fresh labeled with the patient's identification and "biopsy of left kidney #1" is a 2 x 0.1 cm core of tan tissue; submitted entirely for frozen section diagnosis in cassette FSA.

B. BX LEFT KIDNEY #2

Received fresh labeled with the patient's identification and "biopsy of left kidney #2" is a 2.5 x 0.1 cm core of tan tissue; submitted entirely for frozen section diagnosis in cassette FSB.

C. LEFT KIDNEY

Received fresh, labeled as "left kidney" is an intact kidney with attached perinephric fat measuring 15 x 6 x 4 cm and weighs 301 g. Extending from the renal pelvis are a ureter (7.5-cm in length and 0.3 cm in diameter). Tumor does not extend into the ureter, artery or vein and is not present at the resection margin. There is a 2.5 x 1.8 x 1.5 cm well circumscribed, solid, white-tan mass with focal necrosis in the cortex. It is 1.0 cm from the renal hilum. The mass is protruding out of the cortex but grossly appears to be confined by thin renal capsule and does not invade perinephric fat, Gerota's fascia, calyces, or pelvis. There are two additional masses (1.0 x 0.7 x 0.5 cm and 0.4 x 0.3 x 0.3 cm) present in the cortex (same side with the largest mass) located 0.1 cm to each other but at distance from the dominant mass. Both masses are well circumscribed and solid without necrosis. They are 0.4 cm from the renal hilum. Both two masses are confined by renal capsule. Two additional small white nodules (0.1 and 0.3-cm in diameter) are present in the renal surface at the same side with the three larger masses. All masses and white nodules are covered by perinephric fat which is inked blue. Another solid nodule (0.4-cm in greatest dimension) is present in the cortex on the opposite side with the masses and is 0.4 cm to the closest renal capsule. The uninvolved renal parenchyma is tan-brown with a well-defined cortico-medullary junction and orderly cortical striations and medullary rays. The pelvis and calyces appear smooth. There is no adrenal gland present in the specimen. No lymph nodes or stones are identified. Gross photographs are taken. Representative sections are submitted as follows:

C1: Ureter, renal artery, and renal vein resection margins, en face

C2-C3: The largest mass with nearest perinephric fat margin

C4: The largest mass and nearest renal pelvis

C5: Two masses with nearest perinephric fat margin and nearest renal pelvis

C6: One white nodule (0.5-cm) with adjacent kidney

C7: One white nodule (0.1-cm) with adjacent kidney

C8: The solid nodule (0.4-cm) from opposite side with the largest mass

C9: Uninvolved kidney, including renal parenchyma and pelvis

DIAGNOSIS:

A. KIDNEY, LEFT #1, BIOPSY:

- BENIGN RENAL PARENCHYMA

B. KIDNEY, LEFT #2, BIOPSY:

- BENIGN RENAL PARENCHYMA

C. KIDNEY, LEFT, NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA, MULTIFOCAL (2.5 CM LARGEST),

- MULTIPLE ANGIOMYOLIPOMATA (1.0 CM LARGEST).

- SURGICAL MARGINS ARE NOT INVOLVED

[page 2 of 2]
SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: C: LEFT KIDNEY

Specimen Type: Radical nephrectomy

Without adrenal gland

Laterality: Left

Tumor Site: Lower pole

Focality: Multifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 2.5cm

Additional dimensions: 1.8cm x 1.5cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade):

G1: Nuclei round, uniform, approximately 10 u; nucleoli inconspicuous or absent

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Not present

Regional Lymph Nodes: None sampled

Additional Findings: Multiple Angiomyolipomata

Pathological Staging (pTNM): pT 1a (m) N x M x

Comment(s):

Multiple angiomyolipomas associated with renal carcinoma are distinctly unusual (1). Clinical investigation for a genetic disorder (including, but not limited to, tuberous sclerosis) is advised.

1. [REDACTED]

CLINICAL HISTORY:

Question of kidney cancer

PRE-OPERATIVE DIAGNOSIS:

Left kidney mass

[REDACTED]

Source: NCI Genomic Data Commons file 72882106-bd94-40b1-9541-db00d19697b7 (TCGA-G7-6797.9D4D381D-D488-4936-9514-6D5D3084A783.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).